Somatic mutation profile of tumor specimen TCGA-56-1622-01A (aliquot TCGA-56-1622-01A-01W-0782-08) from TCGA case TCGA-56-1622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-56-1622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03772cc8-0056-4538-9e6d-c21fac175330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-1622-11A (Solid Tissue Normal), aliquot TCGA-56-1622-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ce2a928-6b7f-453f-8425-d1df3b01b70f

The open-access MAF lists 256 somatic variants for this specimen: 185 protein-altering or splice-affecting, 64 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 64, Nonsense Mutation 7, Frame Shift Ins 6, Splice Site 6, Frame Shift Del 3, 5'Flank 2, Intron 2, RNA 2, 5'UTR 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 39/49 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55746357; called by muse, mutect2, varscan2
- ABCA1 | c.5057A>T p.H1686L | Missense Mutation (SNP) | VAF 281/317 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV66064169; called by muse, mutect2, varscan2
- ADARB2 | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs996734955, COSV67181919; called by muse, mutect2, varscan2
- AHI1 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55623563, COSV55626363; called by muse, mutect2, varscan2
- APPL2 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 142/159 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51588534; called by muse, mutect2, varscan2
- ARFRP1 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV53926570, COSV53926863; called by muse, mutect2, varscan2
- ARHGEF10L | c.2955G>A p.W985* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV51428797; called by muse, mutect2, varscan2
- ARHGEF2 | c.2209-1G>A p.X737_splice (on ENST00000361247 / NM_001162383.2; = p.X709_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 135/231 reads (58%) | catalogued as COSV58107135, COSV58114043; called by muse, mutect2, varscan2
- BEST1 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV56444675, COSV99861428; called by muse, mutect2, varscan2
- BTNL2 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs745983253, COSV66630245; called by muse, mutect2, varscan2
- C1GALT1C1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs773375422, COSV58973778; called by muse, mutect2, varscan2
- C6orf136 | c.754G>A p.E252K (on ENST00000376473 / NM_001109938.3; = p.E118K on NM_145029.4) | Missense Mutation (SNP) | VAF 118/208 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs776450954, COSV53312391; called by muse, mutect2, varscan2
- CAPSL | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV68437329; called by muse, mutect2, varscan2
- CCDC178 | c.2338A>G p.I780V (on ENST00000383096 / NM_001105528.3; = p.I742V on NM_198995.3) | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55761855; called by muse, mutect2, varscan2
- CCDC38 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 69/80 reads (86%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200003296; called by muse, mutect2, varscan2
- CD207 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69651747; called by muse, mutect2, varscan2
- CD226 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54610390; called by muse, mutect2, varscan2
- CDH11 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51752888, COSV51764246; called by muse, mutect2, varscan2
- CDH18 | c.1637C>G p.T546R | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56904744; called by muse, mutect2, varscan2
- CDH20 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 227/378 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV53004135, COSV53005406; called by muse, mutect2, varscan2
- CDH8 | c.1774T>A p.L592M | Missense Mutation (SNP) | VAF 129/218 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54851192; called by muse, mutect2, varscan2
- CMBL | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 98/597 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56982931; called by muse, mutect2, varscan2
- CNOT6L | c.159G>T p.W53C (on ENST00000504123 / NM_001286790.2; = p.W48C on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53697503; called by muse, mutect2, varscan2
- CNPY1 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as rs1305203139, COSV58786675; called by muse, mutect2, varscan2
- COL3A1 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582805; called by muse, mutect2, varscan2
- COL4A1 | c.3950-1G>C p.X1317_splice | Splice Site (SNP) | VAF 97/119 reads (82%) | catalogued as COSV65422134; called by muse, mutect2, varscan2
- CYP3A43 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs771535128, COSV55935203; called by muse, mutect2, varscan2
- DCTN1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 147/271 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV62619747; called by muse, mutect2, varscan2
- DHFR2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV58934172; called by muse, mutect2, varscan2
- DMXL2 | c.1678A>G p.K560E | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV51841505, COSV99196325; called by muse, mutect2, varscan2
- DNAH17 | c.11774C>A p.A3925D | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67750370; called by muse, mutect2, varscan2
- DPH2 | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52542667; called by muse, mutect2, varscan2
- DPYD | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60075541; called by muse, mutect2, varscan2
- DPYS | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 278/307 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60906729; called by muse, mutect2, varscan2
- EML1 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 153/303 reads (50%) | catalogued as COSV51742077; called by muse, mutect2, varscan2
- EP300 | c.4193T>C p.L1398P | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54327567; called by muse, mutect2, varscan2
- EPS8 | c.365A>T p.K122M | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55528114; called by muse, mutect2, varscan2
- FAM135B | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 722/790 reads (91%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52708219; called by mutect2, varscan2
- FAM135B | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 748/816 reads (92%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52708236; called by mutect2, varscan2
- FAM135B | c.1624G>T p.G542C | Missense Mutation (SNP) | VAF 227/242 reads (94%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.817); catalogued as COSV52708258, COSV52714058; called by muse, mutect2, varscan2
- FLG | c.3945C>G p.D1315E | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.191); catalogued as rs752779456, COSV64237598; called by muse, mutect2, varscan2
- FLG | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64237605; called by muse, mutect2, varscan2
- FOLH1 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV57046281; called by muse, mutect2, varscan2
- FOXRED1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005419; called by muse, mutect2, varscan2
- FRG2B | c.681G>C p.M227I | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV101423547; called by muse, varscan2
- FRY | c.4240C>G p.L1414V | Missense Mutation (SNP) | VAF 154/192 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV66565982; called by muse, mutect2, varscan2
- GALNT17 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV61149750, COSV61155864; called by muse, mutect2, varscan2
- GARNL3 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV59224077, COSV59229221; called by muse, mutect2, varscan2
- GBP6 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65010826; called by muse, mutect2, varscan2
- GLS | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV57840260; called by muse, mutect2, varscan2
- GLUD1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 169/186 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340381250, COSV53277594; called by muse, mutect2, varscan2
- GPM6A | c.71dup p.I25Hfs*25 | Frame Shift Ins (INS) | VAF 62/142 reads (44%) | catalogued as rs1216366348; called by pindel, varscan2
- GPRC5C | c.1409C>T p.P470L (on ENST00000652232; = p.P425L on NM_018653.4) | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs757207937, COSV61235555; called by muse, mutect2, varscan2
- H1-2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.267); catalogued as rs547650580, COSV59189838, COSV59191057; called by mutect2, varscan2
- HAT1 | c.458del p.G153Efs*14 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as COSV51362955; called by mutect2, varscan2
- HERC2 | c.6650T>A p.L2217Q | Missense Mutation (SNP) | VAF 90/103 reads (87%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55310384; called by muse, varscan2
- HLX | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65044383; called by muse, mutect2, varscan2
- IL31 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 86/115 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV65476094; called by muse, varscan2
- IQCD | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1233675060, COSV55320735, COSV55322327; called by muse, mutect2
- ITGA11 | c.2903A>G p.Y968C | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs753174019, COSV59875303; called by muse, mutect2, varscan2
- ITIH6 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 64/72 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54486969, COSV99513798; called by muse, mutect2, varscan2
- KANSL1 | c.2834+1G>C p.X945_splice (on ENST00000574590 / NM_001193465.2; = p.X946_splice on NM_015443.4) | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV52237583; called by muse, mutect2
- KCNH8 | c.1604G>C p.R535P | Missense Mutation (SNP) | VAF 286/322 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60457598, COSV60477558; called by muse, mutect2, varscan2
- KCNIP4 | c.273C>G p.Y91* | Nonsense Mutation (SNP) | VAF 175/235 reads (74%) | catalogued as COSV62846039; called by muse, mutect2, varscan2
- KCNJ15 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768675308, COSV60810326; called by muse, mutect2
- KLHL3 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 94/132 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as rs1394919522, COSV59051170; called by muse, mutect2, varscan2
- KMT2C | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 128/1804 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074418, COSV51341509; called by muse, mutect2
- KREMEN1 | c.1357A>G p.I453V (on ENST00000407188; = p.I455V on NM_032045.5) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); catalogued as rs761023660, COSV59911667; called by muse, mutect2, varscan2
- LCP1 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 123/136 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59939721; called by muse, mutect2, varscan2
- LDB2 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58763449; called by muse, mutect2, varscan2
- LDHAL6A | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 223/275 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs762981632, COSV52648724; called by muse, mutect2, varscan2
- LIPI | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708731; called by muse, mutect2, varscan2
- LMBRD2 | c.1583G>C p.G528A | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV56948846; called by muse, mutect2, varscan2
- LRBA | c.6363G>T p.K2121N | Missense Mutation (SNP) | VAF 163/402 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV58260966; called by muse, mutect2, varscan2
- LRRK2 | c.7124T>C p.V2375A | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); catalogued as rs1192524761, COSV54145521; called by muse, mutect2, varscan2
- MAP3K13 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 32/581 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779365471, COSV53984208; called by muse, mutect2
- MAP3K13 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 30/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1283305765, COSV53984221; called by muse, mutect2
- MME | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 250/296 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64706181; called by muse, mutect2, varscan2
- MMP9 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV63433808, COSV63434510; called by muse, mutect2, varscan2
- MPP4 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59629356; called by muse, mutect2, varscan2
- MRAP | c.107-2A>G p.X36_splice | Splice Site (SNP) | VAF 111/170 reads (65%) | catalogued as COSV57936460; called by muse, mutect2, varscan2
- MROH2B | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 166/321 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV68181657, COSV68183436; called by muse, mutect2, varscan2
- MUC16 | c.25937C>A p.P8646H | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV67448453, COSV67491582; called by muse, mutect2, varscan2
- MYEF2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV51046184; called by muse, mutect2, varscan2
- MYH13 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 117/140 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52821953; called by muse, varscan2
- MYH2 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 157/190 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV55432587, COSV55437494; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 48/184 reads (26%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- NBEA | c.2198A>C p.H733P | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59763551; called by muse, mutect2, varscan2
- NDUFAF6 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV54407339; called by muse, mutect2, varscan2
- NHS | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 245/266 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs779002657, COSV66271970; called by muse, mutect2, varscan2
- NID1 | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV51615679, COSV51620573; called by muse, mutect2, varscan2
- NIPSNAP3B | c.743A>T p.*248Lext*18 | Nonstop Mutation (SNP) | VAF 100/116 reads (86%) | catalogued as COSV66106407; called by muse, mutect2, varscan2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 22/188 reads (12%) | catalogued as rs753725730; called by mutect2, varscan2
- OR2C3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63574532; called by muse, mutect2, varscan2
- OR2L3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV63454567; called by muse, varscan2
- OR2T2 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100737806; called by muse, varscan2
- OR4F6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV61026377; called by muse, mutect2, varscan2
- OR6F1 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 348/525 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV57467020; called by muse, mutect2, varscan2
- OR8K5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57888006; called by muse, mutect2, varscan2
- OR9Q2 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV61111473; called by muse, mutect2, varscan2
- OVCH1 | c.214T>C p.C72R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753299595, COSV55476301; called by muse, mutect2, varscan2
- PAPPA2 | c.4653C>G p.I1551M | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV62791724; called by muse, mutect2, varscan2
- PARD3B | c.2188T>A p.S730T (on ENST00000406610 / NM_001302769.2; = p.S668T on NM_152526.6) | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV62504145; called by muse, mutect2, varscan2
- PCDH11X | c.3563G>T p.R1188L | Missense Mutation (SNP) | VAF 191/232 reads (82%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs746951282, COSV53446521, COSV53467425; called by muse, mutect2, varscan2
- PCDHB10 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV53375930, COSV53384180; called by muse, mutect2, varscan2
- PCDHB2 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.51); catalogued as COSV50564750; called by muse, mutect2, varscan2
- PCLO | c.14365G>A p.V4789M | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61616573, COSV61618641; called by muse, mutect2, varscan2
- PDE5A | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.222); catalogued as COSV53345870; called by muse, mutect2
- PDILT | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56699892; called by muse, mutect2, varscan2
- PLEKHH1 | c.3999dup p.T1334Hfs*56 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs761759640; called by mutect2, varscan2
- PPA2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs1293383364, COSV58993637; called by muse, mutect2, varscan2
- PRRC2C | c.7236G>T p.L2412F (on ENST00000367742; = p.L2410F on NM_015172.4) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV58901844; called by muse, mutect2, varscan2
- PRRC2C | c.7237G>T p.A2413S (on ENST00000367742; = p.A2411S on NM_015172.4) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); catalogued as rs750937319, COSV58901853; called by muse, mutect2, varscan2
- PTPN4 | c.2520G>T p.K840N | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55298065; called by muse, mutect2, varscan2
- RANBP2 | c.9015G>T p.W3005C | Missense Mutation (SNP) | VAF 139/241 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51697209; called by muse, mutect2, varscan2
- RASAL2 | c.3325C>T p.R1109W | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768397267, COSV62710456; called by muse, mutect2, varscan2
- REG3A | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100532652, COSV59408429; called by muse, varscan2
- ROPN1L | c.378G>C p.W126C | Missense Mutation (SNP) | VAF 183/473 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56873078, COSV56874992, COSV99928511; called by muse, mutect2, varscan2
- RPTN | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 247/793 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV60166463; called by muse, mutect2, varscan2
- RYR1 | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 145/395 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090644; called by muse, mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- SAP30BP | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV53126906; called by muse, mutect2, varscan2
- SCN1A | c.3657G>T p.W1219C (on ENST00000303395 / NM_001202435.3; = p.W1208C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM113317, COSV57661967; called by muse, mutect2, varscan2
- SCN1A | c.3656G>T p.W1219L (on ENST00000303395 / NM_001202435.3; = p.W1208L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as CM096102, COSV57661985, COSV57677893; called by muse, mutect2, varscan2
- SCRN1 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV54128706, COSV54128932; called by muse, mutect2, varscan2
- SERPINA5 | c.322C>G p.H108D | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61573642; called by muse, mutect2, varscan2
- SHANK3 | c.4363C>A p.R1455S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as rs762975306, COSV53184133; called by muse, mutect2
- SIM1 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53489403, COSV99491906; called by muse, mutect2, varscan2
- SIM2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV51766454; called by muse, mutect2, varscan2
- SLITRK2 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV59423450; called by muse, mutect2, varscan2
- SMYD2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65290423, COSV65291973; called by muse, mutect2, varscan2
- SP4 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as COSV56021016; called by muse, mutect2, varscan2
- SPRY3 | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 222/571 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57142028; called by muse, mutect2, varscan2
- SPTAN1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63985673; called by muse, mutect2, varscan2
- SRGAP2 | c.3020T>C p.F1007S (on ENST00000624873 / NM_001170637.4; = p.F1008S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.065); catalogued as COSV55333880; called by muse, mutect2, varscan2
- STARD8 | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52922510; called by muse, mutect2, varscan2
- SYNGR4 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 55/97 reads (57%) | catalogued as COSV61225124; called by muse, mutect2, varscan2
- TEX13B | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 131/153 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV57202208; called by muse, mutect2, varscan2
- TIMD4 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 138/171 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs747982212, COSV50854095; called by muse, mutect2, varscan2
- TJP1 | c.4680A>T p.K1560N | Missense Mutation (SNP) | VAF 111/126 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV62039827; called by muse, mutect2, varscan2
- TMX4 | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55679862; called by muse, mutect2, varscan2
- TRIM49 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as COSV61670378; called by muse, mutect2, varscan2
- TRIM51 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV55264248; called by muse, mutect2, varscan2
- TRPS1 | c.413A>T p.D138V (on ENST00000220888 / NM_001330599.2; = p.D151V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV55228430; called by muse, mutect2, varscan2
- TRPS1 | c.412G>T p.D138Y (on ENST00000220888 / NM_001330599.2; = p.D151Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV55228445; called by muse, mutect2, varscan2
- TTN | c.54728T>A p.L18243Q (on ENST00000591111; = p.L10819Q on NM_003319.4) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV59910430; called by muse, mutect2
- UNC13B | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 140/159 reads (88%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV65931627; called by muse, mutect2, varscan2
- UNC13C | c.6228G>T p.Q2076H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52847320; called by muse, mutect2, varscan2
- URB2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV50981877; called by muse, mutect2, varscan2
- USP3 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs1306212576, COSV51426403; called by muse, mutect2, varscan2
- UTP11 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65951072; called by muse, mutect2, varscan2
- VAV1 | c.2446G>C p.G816R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100409074, COSV58379493, COSV58386932; called by muse, mutect2, varscan2
- VPS16 | c.1379G>C p.R460P | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100988418, COSV66792545; called by muse, mutect2, varscan2
- WDR31 | c.780G>C p.T260= (on ENST00000374193 / NM_001006615.3; = p.T259= on NM_145241.5) | Splice Region (SNP) | VAF 203/232 reads (88%) | catalogued as rs148709910, COSV100516581, COSV59145447; called by muse, mutect2, varscan2
- WIF1 | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 48/124 reads (39%) | catalogued as COSV54129952; called by muse, mutect2, varscan2
- ZFP57 | c.1380G>T p.R460S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65305729; called by muse, mutect2, varscan2
- ZNF142 | c.4477G>A p.A1493T (on ENST00000411696 / NM_001379660.1; = p.A1293T on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV68743054; called by muse, mutect2, varscan2
- ZNF234 | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs1384916061, COSV70602900; called by muse, mutect2, varscan2
- ZNF425 | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65200671; called by muse, mutect2, varscan2
- ZNF479 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 20/28 reads (71%) | catalogued as COSV58636354; called by muse, mutect2, varscan2
- ZNF625 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63241297; called by muse, mutect2, varscan2
- ZNF721 | c.2659G>A p.G887S (on ENST00000338977; = p.G899S on NM_133474.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV59089764; called by muse, mutect2, varscan2
- ZNF80 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as rs1331092708, COSV57359967; called by muse, mutect2
- ZNF804B | c.3507G>T p.M1169I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV60818170; called by muse, mutect2, varscan2
- ZNF804B | c.3508C>T p.Q1170* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV60818177; called by muse, mutect2, varscan2
- ZRANB3 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51507492; called by muse, mutect2
- CATSPERD | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- CLASP2 | c.2072-6_2076del p.X691_splice | Splice Site (DEL) | VAF 56/83 reads (67%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.45A>T p.L15F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DARS2 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 4/104 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- DST | c.10053G>T p.L3351F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXL2 | c.187_200del p.I63Pfs*28 | Frame Shift Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, varscan2
- IARS1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- NAGLU | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 32/384 reads (8%) | called by muse, mutect2
- NUS1 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 30/491 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); called by muse, mutect2
- OR2T10 | c.832T>G p.Y278D | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2T35 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- OR52N4 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- PCDHB5 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 27/616 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT7 | c.1508_1523del p.H503Pfs*3 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | called by mutect2, pindel, varscan2
- SERBP1 | c.662C>T p.S221F (on ENST00000370995 / NM_001018067.2; = p.S215F on NM_015640.4) | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.961); called by muse, mutect2
- SYNRG | c.1612A>C p.K538Q | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- USP24 | c.2695dup p.M899Nfs*19 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- UTP18 | c.1628dup p.K544Qfs*6 | Frame Shift Ins (INS) | VAF 78/158 reads (49%) | called by mutect2, varscan2
- ABCA13 | c.1566C>A p.S522= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV70026103; called by muse, mutect2, varscan2
- ADAM2 | c.1053T>C p.F351= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV55859348; called by muse, mutect2, varscan2
- ADGRA3 | c.3513C>T p.H1171= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV51560589; called by muse, mutect2, varscan2
- ANKMY1 | c.522G>T p.S174= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56030750; called by muse, mutect2, varscan2
- ARCN1 | c.9G>T p.L3= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV50614483; called by muse, mutect2, varscan2
- BTN3A3 | c.687G>T p.L229= | Silent (SNP) | VAF 134/253 reads (53%) | catalogued as COSV55071027; called by muse, mutect2, varscan2
- CDH10 | c.534T>C p.S178= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as rs1231628581, COSV52571627, COSV52588846; called by muse, mutect2, varscan2
- CELF4 | c.1083C>T p.G361= | Silent (SNP) | VAF 61/118 reads (52%) | catalogued as COSV58447645; called by muse, mutect2, varscan2
- CHIA | c.351G>A p.Q117= (on ENST00000343320; = p.Q9= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as rs150698600; called by muse, mutect2
- CNTRL | c.2532G>A p.Q844= | Silent (SNP) | VAF 146/179 reads (82%) | catalogued as COSV53044097; called by muse, mutect2, varscan2
- CORIN | c.2595T>C p.H865= | Silent (SNP) | VAF 113/229 reads (49%) | catalogued as COSV56687197; called by muse, mutect2, varscan2
- CRLF2 | c.333C>A p.R111= | Silent (SNP) | VAF 245/639 reads (38%) | catalogued as COSV67493444; called by muse, mutect2, varscan2
- CSGALNACT1 | c.408C>G p.G136= | Silent (SNP) | VAF 67/94 reads (71%) | catalogued as COSV59974436, COSV59981769; called by muse, mutect2, varscan2
- CYBB | c.180G>C p.L60= | Silent (SNP) | VAF 42/44 reads (95%) | catalogued as COSV66084864; called by muse, mutect2, varscan2
- DIAPH3 | c.1218C>T p.R406= (on ENST00000400324 / NM_001042517.2; = p.R143= on NM_030932.3) | Silent (SNP) | VAF 89/126 reads (71%) | catalogued as rs1333703096, COSV57365580; called by muse, mutect2, varscan2
- DNM1 | c.231C>T p.T77= | Silent (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- DUSP21 | c.246C>T p.Y82= | Silent (SNP) | VAF 260/280 reads (93%) | catalogued as rs369441582, COSV59133653; called by muse, mutect2, varscan2
- EFCC1 | c.1624C>T p.L542= | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as rs1489092197, COSV71401776; called by muse, mutect2, varscan2
- ENPP5 | c.627A>T p.S209= | Silent (SNP) | VAF 68/130 reads (52%) | catalogued as COSV57908198; called by muse, mutect2, varscan2
- FAM122A | c.363C>T p.F121= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as rs1267563790, COSV55254613; called by muse, mutect2
- FAM221B | c.624T>A p.P208= | Silent (SNP) | VAF 76/94 reads (81%) | catalogued as COSV65073783; called by muse, varscan2
- FMN2 | c.4629C>T p.L1543= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV60419266; called by muse, mutect2, varscan2
- FRG2C | c.732A>T p.P244= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- GJD2 | c.682T>C p.L228= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as rs1379230828, COSV51747306; called by muse, mutect2, varscan2
- H1-2 | c.114C>T p.P38= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs780590605, COSV59189848; called by mutect2, varscan2
- H1-5 | c.114G>T p.A38= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV100137611, COSV58899165; called by muse, varscan2
- HMGN2 | c.210A>T p.A70= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV63523236; called by muse, mutect2, varscan2
- HS3ST4 | c.828C>T p.S276= | Silent (SNP) | VAF 186/458 reads (41%) | catalogued as COSV58803812; called by muse, mutect2, varscan2
- IGHV1-24 | c.24C>T p.L8= | Silent (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- ITPRID2 | c.1896G>A p.E632= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as COSV57469890; called by muse, mutect2, varscan2
- KLHL1 | c.876T>G p.L292= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV64767719; called by muse, mutect2, varscan2
- LNPK | c.453G>A p.P151= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs757041047, COSV55822603; called by muse, mutect2, varscan2
- LRFN1 | c.831G>A p.T277= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs761845250, COSV50434910; called by muse, mutect2, varscan2
- MAP4K4 | c.1059C>T p.R353= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV56325952; called by muse, mutect2, varscan2
- MOCS1 | c.720C>A p.P240= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs548975858, COSV57933907; called by muse, mutect2, varscan2
- MRPL9 | c.795C>G p.P265= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV58617460; called by muse, mutect2, varscan2
- MRTFA | c.558G>A p.K186= | Silent (SNP) | VAF 73/234 reads (31%) | catalogued as rs933197040, COSV62931591; called by muse, mutect2, varscan2
- NID2 | c.888G>T p.L296= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV53493518; called by muse, mutect2, varscan2
- NRDC | c.2220C>T p.F740= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1290658691, COSV61406046; called by muse, mutect2
- OR1C1 | c.141G>A p.A47= | Silent (SNP) | VAF 54/227 reads (24%) | catalogued as rs200208817, COSV101376230, COSV68715440, COSV68715730; called by muse, mutect2, varscan2
- OR2L2 | c.105A>T p.L35= | Silent (SNP) | VAF 370/602 reads (61%) | catalogued as COSV63548874; called by muse, mutect2, varscan2
- OR51A4 | c.348C>A p.V116= | Silent (SNP) | VAF 175/558 reads (31%) | catalogued as COSV66749120; called by muse, mutect2, varscan2
- OR5D14 | c.567G>T p.V189= | Silent (SNP) | VAF 134/288 reads (47%) | catalogued as COSV59455582, COSV59459193; called by muse, mutect2, varscan2
- OR5T3 | c.66C>A p.T22= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV57379560; called by muse, mutect2, varscan2
- PARP1 | c.1494G>A p.K498= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV64689434; called by muse, varscan2
- PDE4A | c.1560C>T p.D520= (on ENST00000380702 / NM_001111307.2; = p.D281= on NM_006202.3) | Silent (SNP) | VAF 74/236 reads (31%) | catalogued as COSV53351393; called by muse, mutect2, varscan2
- PPP1R13B | c.3051T>C p.G1017= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV52449148; called by muse, mutect2, varscan2
- PRAMEF2 | c.1128C>T p.C376= | Silent (SNP) | VAF 100/394 reads (25%) | catalogued as COSV53572831; called by muse, mutect2, varscan2
- PTCHD3 | c.114G>C p.S38= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs543375628, COSV71256340, COSV71257346; called by muse, mutect2, varscan2
- PTPRB | c.1095G>C p.L365= | Silent (SNP) | VAF 199/389 reads (51%) | catalogued as COSV54234070; called by muse, mutect2, varscan2
- RBM19 | c.258C>A p.P86= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV55688720; called by muse, mutect2, varscan2
- RUNX2 | c.660A>C p.T220= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as COSV61839116; called by muse, mutect2, varscan2
- SCN10A | c.636A>C p.S212= | Silent (SNP) | VAF 199/243 reads (82%) | catalogued as COSV71860450; called by muse, mutect2, varscan2
- SCNN1A | c.1521G>A p.S507= | Silent (SNP) | VAF 390/781 reads (50%) | catalogued as rs368914240; called by muse, mutect2, varscan2
- SCTR | c.522C>T p.R174= | Silent (SNP) | VAF 79/155 reads (51%) | catalogued as COSV50027004; called by muse, mutect2, varscan2
- SLAMF6 | c.327C>A p.A109= | Silent (SNP) | VAF 185/289 reads (64%) | catalogued as COSV63586504; called by muse, mutect2, varscan2
- SLC25A13 | c.1137G>A p.K379= | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as COSV99672995; called by muse, mutect2
- SLC4A10 | c.1767A>C p.S589= (on ENST00000446997 / NM_001354461.2; = p.S559= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 102/225 reads (45%) | catalogued as COSV55766382; called by muse, mutect2, varscan2
- SLC9A9 | c.207T>C p.A69= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs112237207, COSV57219597; called by muse, mutect2, varscan2
- SYNE1 | c.7389T>C p.L2463= (on ENST00000367255 / NM_182961.4; = p.L2470= on NM_033071.3) | Silent (SNP) | VAF 151/271 reads (56%) | catalogued as COSV54919247; called by muse, mutect2, varscan2
- TAS1R2 | c.1161C>T p.S387= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs139739080, COSV64743807; called by muse, mutect2, varscan2
- TMPRSS15 | c.756C>A p.V252= | Silent (SNP) | VAF 188/358 reads (53%) | catalogued as COSV53035550; called by muse, varscan2
- TOX2 | c.888G>T p.L296= (on ENST00000358131 / NM_001098798.2; = p.L245= on NM_032883.3) | Silent (SNP) | VAF 71/145 reads (49%) | catalogued as COSV57883070; called by muse, mutect2, varscan2
- TPTE | c.1485C>T p.Y495= (on ENST00000618007 / NM_199261.4; = p.Y477= on NM_199259.4) | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501627 ins G | 5'Flank (INS) | VAF 46/232 reads (20%) | catalogued as rs1383618828; called by mutect2, pindel, varscan2
- FRMPD2B | n.500G>C | RNA (SNP) | VAF 32/36 reads (89%) | called by mutect2, varscan2
- MARCHF1 | c.-322-85642G>T | Intron (SNP) | VAF 85/101 reads (84%) | catalogued as COSV72275467; called by muse, mutect2, varscan2
- NDUFB9 | c.-1A>G | 5'UTR (SNP) | VAF 96/208 reads (46%) | catalogued as rs556246354, COSV99412989; called by muse, mutect2, varscan2
- PKD1L2 | n.700C>T | RNA (SNP) | VAF 149/379 reads (39%) | catalogued as rs539451747; called by muse, mutect2, varscan2
- TTN | c.10360+5360T>C | Intron (SNP) | VAF 31/56 reads (55%) | catalogued as COSV59910454; called by muse, mutect2, varscan2
- UTS2 | chr1:7853345 G>T | 5'Flank (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2
